Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3930, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3930-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with tumor-free oral and aboral resection margins and including an ulcerated, poorly differentiated adenocarcinoma of the ascending colon, with infiltration of the perimuscular fatty tissue and numerous regional lymph node metastases (G3, pT3, L1, V1 local R0 pN2 24/29).

Source: NCI Genomic Data Commons file 3a20c3d6-90ee-420f-93b3-154d0dba3265 (TCGA-AA-3930.6312F276-158B-4B14-9F8C-1B47ADABB147.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).